CCDI case PBCCNR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8b1b318f-aab6-4096-a9b0-0d4a60565189

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.2 years (5,926 days).

Biospecimens (3 samples)
- Sample 0DOBSV: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DOBT9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOBTH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
